Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A461, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A461-01A (Primary Tumor).

[page 1 of 3]
M

Accession:
Specimen Date/Time:

DIAGNOSIS

- (A) CONTENTS LEVEL 3, LEFT NECK, DISSECTION:
No tumor present in six lymph nodes (0/6)

- (B) TOTAL LARYNGECTOMY, BILATERAL CENTRAL COMPARTMENT AND RIGHT THYROID LOBECTOMY:

Larynx:

INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (5.0 CM), EXTENDING TO PRE-
EPIGLOTTIC SOFT TISSUE
LYMPHOVASCULAR INVASION IS PRESENT
Perineural invasion is not identified
Resection margins are free of tumor
No tumor present in one paratracheal lymph node
Thyroid gland with no diagnostic abnormality

Central compartment lymph node dissection:
No tumor present in fifteen lymph nodes (0/15)

ICD-0-3
carcinoma, squamous cell, NOS 8070/3
Site: larynx, NOS C32.9

lw
10/1/12

- (C) RIGHT LARYNGEAL MARGIN:
Squamous mucosa, no tumor present
- (D) POSTERIOR CRICOID MUCOSA:
Squamous mucosa, no tumor present
- (E) LEFT PYRIFORM SINUS:
Squamous mucosa, no tumor present
- (F) SUPERIOR VALLECULA MARGIN:
Squamous mucosa with lymphoid stroma, no tumor present
- (G) LEFT LARYNGEAL MARGIN:
Squamous mucosa with lymphoid stroma, no tumor present
- (H) RIGHT PYRIFORM SINUS:
Squamous mucosa, no tumor present

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) CONTENTS, LEVEL 3, LEFT NECK - Multiple tan-yellow irregular fragments of hemorrhagic soft tissue, 3.0 x 2.0 x 1.4 cm in aggregate. Seven possible lymph nodes are identified ranging in size from 0.4 x 0.3 x 0.2 cm to 1.5 x 1.3 x 0.8 cm.

SECTION CODE: A1, three possible lymph nodes; A2, two possible lymph nodes; A3, A4, one bisected possible lymph node in each cassette.

(B) TOTAL LARYNGECTOMY, BILATERAL CENTRAL COMPARTMENT AND RIGHT THYROID LOBECTOMY - A total

[page 2 of 3]
Accession:

Specimen Date/Time:

laryngectomy (10.2 x 8.3 x 4.5 cm) and attached right lobe of thyroid (4.5 x 3.0 x 1.2 cm) anteriorly contains muscle and soft tissue, and an elliptical stoma (3.0 x 2.2 cm).

An ulcerated, nodular and polypoid tumor extends from the posterior superior aspect of the epiglottis, coming to within 1.0 cm of the tip and 0.5 cm from the right and left aryepiglottic folds. The tumor extends 5.0 cm from superior to inferior, 3.5 cm from right to left and 3 cm deep. The tumor is presented bilaterally in the supra glottis and is polypoid at the left false vocal cord, however does not extend to the true vocal cords on the right or left. The tumor is 4.2 cm above the distal tracheal margin and 3.0 cm above the stoma. Subglottic extension is not identified. The tumor fills the pre-epiglottic space and extends to the hyoid bone anterior superiorly, with a scant fibrous tissue covering over the superior aspect of the tumor. The tumor abuts the thyroid cartilage and appears to invade it anteriorly.

The right lobe of thyroid is glassy pink-brown and lobular. No masses are identified. Within the fibroadipose tissue, multiple lymph nodes are identified.

SECTION CODE: B1-B2, tracheal margin for frozen section en face; B3, unremarkable subglottic mucosa from right trachea; B4, superior aspect of epiglottis; B5-B6, left and right more inferior; B7-B8, left and right epiglottis more inferior; B9-B10, right epiglottis more inferior; B11-B12, right and left epiglottis more inferior; B13 and B14, tumor behind left and right behind hyoid bone; B15, vertical section through left true vocal cord; B16, vertical through right true vocal cord; B17, left arytenoid; B18, right arytenoid; B19, stoma; B20, right thyroid; B21-B25, nodes from left side of neck (B21-B24, one bisected node in each block, B25, 5 whole nodules); B26-B29, possible lymph nodes from right side of neck (B26-B28, one nodule bisected in each cassette, B29, two whole nodes); B30, two whole possible lymph nodes centrally located.

*FS/DX: TRACHEAL MARGIN FREE OF TUMOR.

(C) RIGHT LARYNGEAL MARGIN - A linear portion of pink soft tissue and mucosa (2.0 x 0.2 x 0.1 cm) is entirely submitted for frozen in C.

*FS/DX: NO TUMOR PRESENT.

(D) POSTERIOR CRICOID MUCOSA - A linear portion of pink soft tissue and mucosa (1.6 x 0.3 x 0.2 cm) is entirely submitted for frozen in D.

*FS/DX: NO TUMOR PRESENT.

(E) LEFT PYRIFORM SINUS - A linear portion of pink soft tissue and mucosa (1.5 x 0.3 x 0.2 cm) is entirely submitted for frozen in E.

*FS/DX: NO TUMOR PRESENT.

(F) SUPERIOR VALLECULA MARGIN - A linear portion of pink soft tissue and mucosa (1.6 x 0.3 x 0.3 cm) is entirely submitted for frozen in F.

*FS/DX: NO TUMOR PRESENT.

(G) LEFT LARYNGEAL MARGIN - A linear portion of pink soft tissue and mucosa (2.0 x 0.3 x 0.2 cm) is entirely submitted for frozen in G.

*FS/DX: NO TUMOR PRESENT.

(H) RIGHT PYRIFORM SINUS - A linear portion of pink soft tissue and mucosa (2.2 x 0.4 x 0.1 cm) is entirely submitted for frozen in H.

*FS/DX: NO TUMOR PRESENT.

CLINICAL HISTORY

None given.

SNOMED CODES

T-24000, M-80703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

-----END OF REPORT-----

[page 3 of 3]
Page: 3

M

Accession:

Specimen Date/Time:

7/9/12

Source: NCI Genomic Data Commons file f689e300-630c-4704-9105-b29588e5f685 (TCGA-CV-A461.35DE8C74-C627-4553-A7AE-A16FF1868BD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).